Somatic mutation profile of tumor specimen C3L-00810-54 (aliquot CPT0262010002) from CPTAC case C3L-00810, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 63.8 years (23,309 days).
Specimen C3L-00810-54: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ebc84789-c90a-4432-99ce-fb5b78861f2b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00810-50 (Buccal Cell Normal), aliquot CPT0262000002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e486b8e4-80cc-435c-8853-7e1dad09fc28

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Frame Shift Ins 1, 3'UTR 1, Nonsense Mutation 1, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 13/46 reads (28%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTPN11 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 51/124 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs121918454, CM013417, COSV61005613, COSV61008344, COSV61012146; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- CTHRC1 | c.193C>T p.R65* | Nonsense Mutation (SNP) | VAF 54/248 reads (22%) | catalogued as rs748382570; called by muse, mutect2, varscan2
- PCDHB15 | c.742G>C p.E248Q | Missense Mutation (SNP) | VAF 60/109 reads (55%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.101); catalogued as rs1554291895, COSV99178874; called by muse, mutect2, varscan2
- PCDHA6 | c.626A>G p.N209S | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SUPT20H | c.1273C>A p.H425N (on ENST00000350612 / NM_001014286.3; = p.H426N on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/186 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- TTN | c.17269G>A p.A5757T (on ENST00000591111; = p.A4830T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/93 reads (51%) | PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CSGALNACT2 | c.1356G>C p.V452= | Silent (SNP) | VAF 60/108 reads (56%) | called by muse, varscan2
- MRPL21 | c.553+238G>C | Intron (SNP) | VAF 4/42 reads (10%) | catalogued as rs1611798; called by mutect2, varscan2
- RB1CC1 | c.*108G>A | 3'UTR (SNP) | VAF 36/99 reads (36%) | catalogued as rs745321743; called by muse, varscan2
